Somatic mutation profile of tumor specimen TCGA-CF-A3MH-01A (aliquot TCGA-CF-A3MH-01A-11D-A20D-08) from TCGA case TCGA-CF-A3MH, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: Low Grade; Age at diagnosis: 75.2 years (27,458 days).
Specimen TCGA-CF-A3MH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9df1f5c7-fee8-480c-8a80-927e6b74c658.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CF-A3MH-10A (Blood Derived Normal), aliquot TCGA-CF-A3MH-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7c5df1d-8366-48c4-a5df-e09a390f0599

The open-access MAF lists 45 somatic variants for this specimen: 35 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 9, Frame Shift Ins 2, Intron 1, Splice Site 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AADACL4 | c.1204A>T p.S402C | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV66106807; called by muse, mutect2
- ADAMTSL3 | c.3289G>C p.D1097H | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV54458895; called by muse, mutect2, varscan2
- ADH6 | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52957017; called by muse, mutect2, varscan2
- ANKRD44 | c.924T>A p.S308R | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as COSV56560367; called by muse, mutect2
- ANXA2 | c.912G>T p.R304S | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV60317887; called by muse, mutect2, varscan2
- ATP4A | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs199790968, COSV52869449; called by muse, mutect2, varscan2
- C15orf39 | c.2708G>A p.R903H | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs939534001, COSV62297475; called by muse, mutect2, varscan2
- CATSPERG | c.1301T>C p.V434A | Missense Mutation (SNP) | VAF 85/199 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV53051280; called by muse, mutect2, varscan2
- CYP2B6 | c.1219G>T p.A407S | Missense Mutation (SNP) | VAF 126/242 reads (52%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as COSV57844889, COSV57844936; called by muse, mutect2, varscan2
- EIF4G3 | c.4330A>G p.I1444V | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.764); catalogued as COSV51688399; called by muse, mutect2, varscan2
- F11 | c.1771G>A p.G591S | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53002608; called by muse, mutect2, varscan2
- FAM110B | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.254); catalogued as rs1333658589, COSV64064894, COSV64066564; called by muse, mutect2, varscan2
- HPS4 | c.447del p.N149Kfs*26 | Frame Shift Del (DEL) | VAF 53/156 reads (34%) | catalogued as COSV61104486; called by mutect2, pindel, varscan2
- KLK15 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as COSV56826274; called by muse, mutect2, varscan2
- KRT20 | c.1178-2A>T p.X393_splice | Splice Site (SNP) | VAF 31/82 reads (38%) | catalogued as COSV51425530; called by muse, mutect2, varscan2
- MASP1 | c.1042G>C p.E348Q | Missense Mutation (SNP) | VAF 93/257 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as COSV51462069; called by muse, mutect2, varscan2
- MUC5B | c.13739C>T p.T4580I | Missense Mutation (SNP) | VAF 95/114 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs781765336, COSV71594247; called by muse, mutect2, varscan2
- NLRP3 | c.2684C>T p.T895M | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs756586843, COSV60228685; called by muse, mutect2, varscan2
- PCLO | c.14719A>G p.T4907A | Missense Mutation (SNP) | VAF 90/282 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs555710577, COSV61651657; called by muse, mutect2, varscan2
- PDP1 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs775429341, COSV52602931; called by muse, mutect2, varscan2
- PIP4P2 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV53439840, COSV99575343; called by muse, mutect2, varscan2
- PREX2 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs760821149, COSV55750174, COSV55773785; called by muse, mutect2, varscan2
- SARS1 | c.838C>T p.H280Y | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52322144; called by muse, mutect2, varscan2
- SH3BP2 | c.1103dup p.R369Kfs*26 | Frame Shift Ins (INS) | VAF 100/155 reads (65%) | catalogued as rs1560111269; called by mutect2, pindel, varscan2
- THEMIS | c.1869C>A p.S623R | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs373253093; called by muse, mutect2, varscan2
- TLR7 | c.2248C>T p.R750* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as rs200283411, COSV66124265; called by muse, mutect2
- TMCC2 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.848); catalogued as rs769495685, COSV58004926; called by muse, mutect2, varscan2
- TNFRSF10A | c.894G>C p.E298D | Missense Mutation (SNP) | VAF 76/87 reads (87%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV55326442; called by muse, mutect2, varscan2
- TRPM2 | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV55973441; called by muse, mutect2, varscan2
- TTN | c.101488G>C p.D33830H (on ENST00000591111; = p.D26406H on NM_003319.4) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | PolyPhen benign (0.134); catalogued as COSV60207054; called by muse, mutect2, varscan2
- TTN | c.77617G>A p.V25873I (on ENST00000591111; = p.V18449I on NM_003319.4) | Missense Mutation (SNP) | VAF 62/136 reads (46%) | PolyPhen benign (0.001); catalogued as rs745920301, COSV59864357; called by muse, mutect2, varscan2
- WNK1 | c.6958A>G p.M2320V (on ENST00000315939 / NM_018979.4; = p.M2072V on NM_014823.3) | Missense Mutation (SNP) | VAF 77/121 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as rs144574284, COSV57273601; called by muse, mutect2, varscan2
- ZFAND4 | c.1562C>T p.S521F | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV60858346; called by muse, mutect2
- ZFP69B | c.740G>C p.R247T | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.233); catalogued as COSV64315835; called by muse, mutect2, varscan2
- ANKFY1 | c.1912_1913dup p.L639Hfs*11 | Frame Shift Ins (INS) | VAF 49/150 reads (33%) | called by mutect2, pindel, varscan2
- ATG16L1 | c.924G>T p.V308= (on ENST00000392017 / NM_030803.7; = p.V289= on NM_017974.4) | Silent (SNP) | VAF 42/87 reads (48%) | catalogued as COSV61466970; called by muse, mutect2, varscan2
- C2orf66 | c.153G>A p.K51= | Silent (SNP) | VAF 48/135 reads (36%) | catalogued as COSV61099019; called by muse, mutect2, varscan2
- GALNT8 | c.429C>G p.L143= | Silent (SNP) | VAF 93/143 reads (65%) | catalogued as COSV52896655, COSV52899559; called by muse, mutect2, varscan2
- GIT2 | c.1119G>A p.L373= (on ENST00000355312 / NM_057169.5; = p.L375= on NM_014776.5) | Silent (SNP) | VAF 55/217 reads (25%) | catalogued as COSV58083287; called by muse, mutect2, varscan2
- KRTAP27-1 | c.453C>T p.F151= | Silent (SNP) | VAF 94/209 reads (45%) | catalogued as rs781274963, COSV67000922; called by muse, mutect2, varscan2
- LCE3D | c.150C>T p.G50= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as rs139649941, COSV64230545; called by muse, mutect2, varscan2
- SLC18B1 | c.267A>G p.V89= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV51595502; called by muse, mutect2, varscan2
- SLC2A13 | c.234C>T p.P78= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs949603127; called by muse, varscan2
- ZFYVE19 | c.1065T>C p.D355= (on ENST00000355341 / NM_001077268.2; = p.D345= on NM_032850.5) | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV54541465; called by muse, mutect2, varscan2
- RABGGTB | c.4-398G>C | Intron (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100174949; called by muse, mutect2, varscan2
